Gene-level copy-number profile of specimen HCM-WCMC-0504-C18-85A from HCMI case HCM-WCMC-0504-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G4; Age at diagnosis: 58.6 years (21,389 days).
Specimen HCM-WCMC-0504-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Cryopreserved; Passage count: 15.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a5e7bcbe-4fec-404d-944c-0be28817af17.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-WCMC-0504-C18-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/0717efc8-210a-490b-ac52-dc45c2efe429

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 43; copy number 2: 55,830; copy number 3: 2,511; copy number 4: 15; copy number 5: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:39,451,045–39,522,852, 1 gene, copy number 5: ADAM3A.

Autosomal genes at a single copy (total copy number 1): 41. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
